Somatic mutation profile of tumor specimen TARGET-10-PARCFM-09A (aliquot TARGET-10-PARCFM-09A-01D) from TARGET case TARGET-10-PARCFM, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.1 years (5,160 days).
Specimen TARGET-10-PARCFM-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ca670a8e-6cb6-4634-9a16-6d5e4167325a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARCFM-10A (Blood Derived Normal), aliquot TARGET-10-PARCFM-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5adeb21c-7bd4-4d81-94c6-26ad91ee5b20

The open-access MAF lists 11 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 3, Missense Mutation 3, Silent 2, RNA 1, Nonsense Mutation 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.7379C>A p.S2460* (on ENST00000358273 / NM_001042492.3; = p.S2439* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 19/23 reads (83%) | catalogued as COSV62192518; called by muse, mutect2, varscan2
- PCLO | c.1889C>T p.T630M | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as rs201668310; called by muse, mutect2, varscan2
- PLEKHA6 | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs267598321, COSV55336633; called by muse, mutect2, varscan2
- BBS7 | c.757G>A p.G253R | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZMYM3 | c.1150_1151insGCGGAG p.S383_V384insGG | In Frame Ins (INS) | VAF 28/32 reads (88%) | called by pindel, varscan2
- KIAA1549 | c.4494C>T p.P1498= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as rs764543415; called by muse, mutect2, varscan2
- KIF26A | c.3810G>T p.L1270= | Silent (SNP) | VAF 5/56 reads (9%) | called by muse, mutect2
- AC092471.1 | n.650G>A | RNA (SNP) | VAF 24/61 reads (39%) | catalogued as rs1012239147; called by muse, mutect2, varscan2
- EIF3I | c.640-23T>C | Intron (SNP) | VAF 34/184 reads (18%) | catalogued as COSV61890294; called by muse, mutect2, varscan2
- EIF3J | c.571+34G>A | Intron (SNP) | VAF 25/60 reads (42%) | called by muse, mutect2, varscan2
- RHOBTB2 | c.193-26G>T | Intron (SNP) | VAF 5/28 reads (18%) | catalogued as rs780637599; called by muse, mutect2
